Somatic mutation profile of cancer-model specimen HCM-CSHL-0768-C56-85B (3D Organoid, passage 4; aliquot HCM-CSHL-0768-C56-85B-01D-A88G-36), derived from the primary tumor of HCMI case HCM-CSHL-0768-C56, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Primary diagnosis: Serous surface papillary carcinoma; Tissue or organ of origin: Ovary; FIGO stage: Stage II; Tumor grade: High Grade.
Specimen HCM-CSHL-0768-C56-85B: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 4.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3b57b8c1-118c-4933-b56f-000d903e989b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0768-C56-10A (Blood Derived Normal), aliquot HCM-CSHL-0768-C56-10A-01D-A88G-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a8eb3806-151b-4cea-8b27-30385ed3a268

The open-access MAF lists 49 somatic variants for this specimen: 38 protein-altering or splice-affecting, 10 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 31, Silent 10, Nonsense Mutation 5, In Frame Del 1, Intron 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.745A>T p.R249W | Missense Mutation (SNP) | VAF 205/220 reads (93%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.838); catalogued as rs587782082, COSV52662247, COSV52676356, COSV52892337, COSV52908430; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ABCC5 | c.3799C>T p.R1267* | Nonsense Mutation (SNP) | VAF 127/384 reads (33%) | catalogued as COSV55593485; called by muse, mutect2, varscan2
- ARFGEF2 | c.3022G>C p.G1008R | Missense Mutation (SNP) | VAF 21/543 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as CM146175; called by muse, mutect2
- ATP10A | c.514C>T p.R172C | Missense Mutation (SNP) | VAF 77/303 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.022); catalogued as rs1381646630, COSV63519072; called by muse, mutect2, varscan2
- DEFB124 | c.95G>A p.G32E | Missense Mutation (SNP) | VAF 20/561 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV58343834; called by muse, mutect2
- GGT5 | c.329G>A p.R110Q | Missense Mutation (SNP) | VAF 25/213 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as rs778920445; called by muse, mutect2, varscan2
- GRK3 | c.832G>A p.D278N | Missense Mutation (SNP) | VAF 203/217 reads (94%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs748016202; called by muse, mutect2, varscan2
- MED30 | c.490C>T p.R164* | Nonsense Mutation (SNP) | VAF 44/694 reads (6%) | catalogued as rs747290267, COSV99815916; called by muse, mutect2
- NPIPB15 | c.667C>T p.R223C | Missense Mutation (SNP) | VAF 52/424 reads (12%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.036); catalogued as rs375786148; called by muse, mutect2, varscan2
- PCNT | c.5266A>G p.M1756V | Missense Mutation (SNP) | VAF 248/519 reads (48%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as rs769923170; called by muse, mutect2, varscan2
- PHYKPL | c.466C>T p.R156C | Missense Mutation (SNP) | VAF 111/356 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.846); catalogued as rs757976712, COSV57425767; called by muse, mutect2, varscan2
- PREX1 | c.1697C>T p.A566V | Missense Mutation (SNP) | VAF 38/442 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.298); catalogued as rs756415189; called by muse, mutect2
- RINL | c.1519G>A p.A507T (on ENST00000591812 / NM_001195833.2; = p.A393T on NM_198445.4) | Missense Mutation (SNP) | VAF 291/585 reads (50%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.969); catalogued as rs1173818428; called by muse, mutect2, varscan2
- ROBO1 | c.1400C>T p.A467V | Missense Mutation (SNP) | VAF 49/438 reads (11%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.953); catalogued as rs781271571; called by muse, mutect2, varscan2
- SAMD9L | c.4016G>A p.R1339K | Missense Mutation (SNP) | VAF 99/308 reads (32%) | SIFT tolerated (0.8); PolyPhen benign (0.015); catalogued as rs1346276637; called by muse, mutect2, varscan2
- SLC26A9 | c.578G>A p.G193D | Missense Mutation (SNP) | VAF 40/289 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1321338169; called by muse, mutect2, varscan2
- SPTA1 | c.5533G>A p.G1845R | Missense Mutation (SNP) | VAF 30/311 reads (10%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.857); catalogued as rs769218124, COSV63748867; called by muse, mutect2, varscan2
- AKR7A2 | c.118T>G p.S40A | Missense Mutation (SNP) | VAF 363/618 reads (59%) | SIFT tolerated (0.13); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- APMAP | c.472G>A p.G158R | Missense Mutation (SNP) | VAF 30/572 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.092); called by muse, mutect2
- ATF6 | c.874G>C p.V292L | Missense Mutation (SNP) | VAF 100/301 reads (33%) | SIFT tolerated (0.5); PolyPhen benign (0); called by muse, mutect2, varscan2
- BCAS1 | c.1660G>A p.G554R | Missense Mutation (SNP) | VAF 235/654 reads (36%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.589); called by muse, mutect2, varscan2
- CA10 | c.555T>A p.F185L | Missense Mutation (SNP) | VAF 14/184 reads (8%) | SIFT tolerated (0.35); PolyPhen benign (0.338); called by muse, mutect2
- CCDC86 | c.738G>A p.W246* | Nonsense Mutation (SNP) | VAF 149/245 reads (61%) | called by muse, mutect2, varscan2
- CCKAR | c.905C>A p.A302E | Missense Mutation (SNP) | VAF 46/528 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- CSMD3 | c.8786A>T p.K2929I (on ENST00000297405 / NM_001363185.1; = p.K2760I on NM_052900.3) | Missense Mutation (SNP) | VAF 126/605 reads (21%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- ECHDC3 | c.847_874del p.G283Rfs*49 | Frame Shift Del (DEL) | VAF 70/220 reads (32%) | called by pindel, varscan2
- GNAL | c.76C>A p.P26T | Missense Mutation (SNP) | VAF 57/367 reads (16%) | SIFT tolerated, low confidence (0.73); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- GOLGA6C | c.611C>A p.T204N | Missense Mutation (SNP) | VAF 106/384 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- IPP | c.577_582del p.S193_I194del | In Frame Del (DEL) | VAF 122/404 reads (30%) | called by mutect2, pindel, varscan2
- ITM2C | c.130C>T p.P44S | Missense Mutation (SNP) | VAF 24/378 reads (6%) | SIFT tolerated (0.22); PolyPhen benign (0.007); called by muse, mutect2
- MUC5B | c.13823G>T p.S4608I | Missense Mutation (SNP) | VAF 217/765 reads (28%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0); called by muse, mutect2, varscan2
- PIK3R2 | c.574G>A p.A192T | Missense Mutation (SNP) | VAF 277/559 reads (50%) | SIFT tolerated (0.08); PolyPhen benign (0); called by muse, mutect2, varscan2
- SAV1 | c.139C>T p.R47* | Nonsense Mutation (SNP) | VAF 168/187 reads (90%) | called by muse, mutect2, varscan2
- SCARF2 | c.1921G>T p.A641S | Missense Mutation (SNP) | VAF 14/378 reads (4%) | SIFT tolerated (0.74); PolyPhen benign (0.108); called by muse, mutect2
- SPRR3 | c.70C>G p.P24A | Missense Mutation (SNP) | VAF 47/435 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- SRFBP1 | c.1070A>T p.N357I | Missense Mutation (SNP) | VAF 60/210 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); called by muse, mutect2, varscan2
- THSD7A | c.337A>T p.K113* | Nonsense Mutation (SNP) | VAF 114/381 reads (30%) | called by muse, mutect2, varscan2
- TNS2 | c.1221G>T p.W407C (on ENST00000314250 / NM_170754.4; = p.W417C on NM_015319.2) | Missense Mutation (SNP) | VAF 267/286 reads (93%) | SIFT tolerated (0.42); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- AKAP6 | c.2214T>C p.D738= | Silent (SNP) | VAF 13/274 reads (5%) | called by muse, mutect2
- CD3E | c.586C>A p.R196= | Silent (SNP) | VAF 240/414 reads (58%) | called by muse, varscan2
- EFR3A | c.1438T>C p.L480= | Silent (SNP) | VAF 600/779 reads (77%) | called by muse, mutect2, varscan2
- FES | c.1788C>T p.L596= | Silent (SNP) | VAF 95/350 reads (27%) | called by muse, mutect2, varscan2
- HCN3 | c.1290C>T p.A430= | Silent (SNP) | VAF 119/475 reads (25%) | called by muse, mutect2, varscan2
- HTR3D | c.1233C>T p.H411= (on ENST00000382489 / NM_001163646.2; = p.H236= on NM_182537.3) | Silent (SNP) | VAF 71/656 reads (11%) | catalogued as rs550781623; called by muse, mutect2, varscan2
- IL1F10 | c.324C>T p.S108= | Silent (SNP) | VAF 105/425 reads (25%) | catalogued as rs375615196; called by muse, mutect2, varscan2
- OR2A5 | c.783C>A p.A261= | Silent (SNP) | VAF 123/355 reads (35%) | catalogued as COSV68738975; called by muse, mutect2
- R3HCC1L | c.786A>T p.G262= | Silent (SNP) | VAF 200/372 reads (54%) | catalogued as rs1279143201, COSV54404105; called by muse, mutect2, varscan2
- ZNF670 | c.306A>G p.P102= | Silent (SNP) | VAF 207/386 reads (54%) | catalogued as rs763924657; called by muse, mutect2, varscan2
- AP1S3 | c.292-4947G>A | Intron (SNP) | VAF 84/306 reads (27%) | called by muse, mutect2, varscan2
